Somatic mutation profile of tumor specimen TARGET-30-PAUHIK-01A (aliquot TARGET-30-PAUHIK-01A-01D) from TARGET case TARGET-30-PAUHIK, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Pelvis, NOS; Age at diagnosis: 0.0 years (17 days).
Specimen TARGET-30-PAUHIK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8968b2e6-2668-4739-9f3c-75d416c465a9.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAUHIK-10A (Blood Derived Normal), aliquot TARGET-30-PAUHIK-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b8728e18-85bf-455f-9754-4b297f8ba6ee

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LAMA1 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 27/203 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs772486258, COSV67531082, COSV67539498; called by muse, mutect2, varscan2
- MYH2 | c.4339G>T p.A1447S | Missense Mutation (SNP) | VAF 21/220 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.176); catalogued as rs765747036, COSV99821319; called by muse, mutect2, varscan2
